Somatic mutation profile of tumor specimen 0DVCF5 from CCDI case PBCLRU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.4 years (499 days).
Specimen 0DVCF5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c09ec0c9-0462-4323-bd5f-02708d057fb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebef7924-d7ae-445f-84a4-0f903d7d983a

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Intron 1, Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXorf56 | c.574G>A p.E192K (on ENST00000536133 / NM_001170570.2; = p.E206K on NM_022101.4) | Missense Mutation (SNP) | VAF 483/1190 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- SMARCB1 | c.996_1006dup p.A336Vfs*105 (on ENST00000263121; = p.A382Vfs*105 on NM_003073.5) | Frame Shift Ins (INS) | VAF 184/237 reads (78%) | called by mutect2, varscan2
- GTF2H1 | c.*43A>G | 3'UTR (SNP) | VAF 239/549 reads (44%) | catalogued as COSV99786384; called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
